Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A4I1, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A4I1-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE:

PATIENT NBR:

PAT TYPE:

PAGE #:

2

SEX: F

ADM DATE:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

A -year-old female with papillary thyroid cancer.

PROCEDURE: SPGD

VERIFIED BY:

1. "parathyroid tissue"

Received is a 0.002 gram, 0.3 cm red tissue bit submitted for frozen section analysis.

1A. Frozen section control.

2. "Thyroid" Received in formalin in a small container is a thyroidectomy specimen, 25.01 gm consisting of a right lobe, 5.5 cm x 3.2 x 1.5 cm, a left lobe, 4.5 x 2.2 x 1.6 cm, and an isthmus, 3.0 x 1.5 x 0.8 cm. The right lobe is serially sectioned by tissue procurement to reveal a 2.2 cm white encapsulated lesion appearing free of margins and unremarkable mahogany parenchyma in other cut sections. The isthmus is serially sectioned to reveal unremarkable tan mahogany parenchyma as is the right lobe of thyroid which shows a 0.4 cm white whorled nodule.

2A-C. Representative sections through right lobe lesion.

2D. Sections sampling grossly unremarkable right (green), left (blue) and isthmus (yellow of thyroid).

2E-F. Small lesion described in left lobe of thyroid.

3. "Level VI lymph node"

Received in a small container filled with formalin is an aggregate of fibroadipose material 4.5 cm x 1.5 cm 0.5 cm. Specimen is dissected and does not reveal definitive lymph node candidates. in 4 cassettes.

FROZEN SECTION REPORT

1. Parathyroid tissue present.

I, , have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

ICD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, nos < 73.9

PROCEDURE: SPMI

VERIFIED BY:

PAPILLARY THYROID CARCINOMA

Size of largest primary tumor: 2.2 cm.

Location(s): Right lobe.

hw
10/1/12

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

NAME: [REDACTED]

BIRTHDATE:

PAGE #: 3

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

REQ DOC: [REDACTED]

Capsular Invasion: Yes.

Vascular Invasion: No.

Margins: Positive (Right lobe)

Extrathyroidal extension: No.

Lymph node metastases: No.

SIDE	LEVEL	#POSITIVE NODES	#TOTAL NODES
Right	VI	0	4
Total Right All (add above)		0	4

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1. "Parathyroid tissue", excision: Unremarkable parathyroid tissue.

2. Thyroid, total thyroidectomy: Right papillary thyroid carcinoma (2.2 cm). Capsular invasion noted. Margins focally positive on right lobe. Small focus of papillary thyroid carcinoma in left lobe (0.4 cm), left margins negative. Please see TEMPLATE for details.

3. "Level VI lymph node", excision: Four lymph nodes, negative for malignancy (0/4). Unremarkable thymus tissue.

I, [REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Code:

FC:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 531e4837-9431-457d-8913-b7856d14241d (TCGA-KS-A4I1.EB9FD285-55AF-4E8F-9C89-74BAA1C0D344.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).